TCGA case TCGA-06-1086 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97686ab2-3b7e-4b21-9bf3-9a5a01709e04

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Dead; Days to death: 208 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 42.8 years (15,645 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 59 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 73 days; Days to treatment end: 194 days; Number of cycles: 3; Treatment dose: 400 mg; Route of administration: Oral.

Follow-up (3 entries)
- Days to follow up: 193 days; Disease response: With Tumor.
- Days to follow up: 208 days; Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-1086-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-06-1086-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-06-1086-01A-01-BS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-06-1086-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-1086-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 208 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 208 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 208 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-06-1086-01): tumor purity 0.89, ploidy 3.24, whole-genome doublings 1 (call status: legacy_call).
